Somatic mutation profile of tumor specimen C3L-02170-03 (aliquot CPT0175560006) from CPTAC case C3L-02170, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 73.1 years (26,717 days).
Specimen C3L-02170-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93441246-9075-4e45-a330-867645f46115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02170-31 (Blood Derived Normal), aliquot CPT0175640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f5bea2-31fd-446b-a715-1b34e192a63e

The open-access MAF lists 133 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 31, Intron 8, Nonsense Mutation 5, Splice Site 2, 5'UTR 2, 3'UTR 2, Splice Region 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 27/527 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANK2 | c.8020A>G p.K2674E | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.164); catalogued as COSV52170383; called by muse, mutect2
- ANKRD26 | c.4907C>G p.S1636* | Nonsense Mutation (SNP) | VAF 9/244 reads (4%) | catalogued as COSV65775712; called by muse, mutect2
- BCHE | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV52256586; called by muse, mutect2
- C1orf87 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100967264; called by muse, mutect2
- CD40LG | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as CM980316; called by muse, mutect2
- CDC20B | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 22/572 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1308062287; called by muse, mutect2
- CDH10 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV52582547; called by muse, mutect2
- EML6 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 53/534 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as rs1292438147; called by muse, mutect2
- ERICH3 | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 17/361 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV58612287; called by muse, mutect2
- EYA2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs774269626; called by muse, mutect2
- FRY | c.8681C>A p.S2894Y | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV66511288; called by muse, mutect2
- ISLR2 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV100679672; called by muse, mutect2
- KIRREL1 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV63286656; called by muse, mutect2
- KRTAP13-1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as rs771638413, COSV62663056; called by muse, mutect2
- NF1 | c.4255G>T p.V1419F (on ENST00000358273 / NM_001042492.3; = p.V1398F on NM_000267.3) | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CD004092; called by muse, mutect2
- NOP53 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV99064907; called by muse, mutect2
- NUMBL | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV53284555; called by muse, mutect2
- PDGFRA | c.485A>G p.H162R | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs916537173; called by muse, mutect2
- PTPRT | c.1631A>G p.K544R | Missense Mutation (SNP) | VAF 32/499 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs375343257; called by muse, mutect2
- SI | c.3975C>A p.N1325K | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV52297121; called by muse, mutect2
- SPATA31D1 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1444949054; called by muse, mutect2
- TPP2 | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65754194; called by muse, mutect2
- TRPV6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs866319889; called by muse, mutect2
- USH2A | c.14476C>A p.P4826T | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV56435817; called by muse, mutect2
- WDR97 | c.2045A>G p.H682R | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1183547616; called by muse, mutect2
- ABCF2 | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTSL3 | c.4954G>T p.G1652W | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.849); called by muse, mutect2
- ANK1 | c.3700A>T p.T1234S | Missense Mutation (SNP) | VAF 26/379 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- ANKRD50 | c.3076A>T p.K1026* | Nonsense Mutation (SNP) | VAF 13/328 reads (4%) | called by muse, mutect2
- AP5B1 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2
- BDKRB2 | c.13T>A p.W5R | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); called by muse, mutect2
- BLK | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 37/778 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- C10orf71 | c.2271G>C p.R757S | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- CCR6 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDC42BPA | c.5068G>T p.D1690Y (on ENST00000334218 / NM_001366019.2; = p.D1677Y on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH12 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDH12 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- CNR1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2
- COPE | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2
- DCAF12L2 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- DGKE | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.262); called by muse, mutect2
- DISP3 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- DNAH9 | c.6974G>T p.C2325F | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- ENTHD1 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2
- FCSK | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- FLG2 | c.6377A>T p.Y2126F | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- FSHB | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- IGSF22 | c.1997C>A p.T666N | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- INSRR | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2
- KDM5A | c.3216G>A p.Q1072= | Splice Region (SNP) | VAF 11/347 reads (3%) | called by muse, mutect2
- KMT2A | c.9874A>G p.S3292G | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KY | c.1366T>A p.W456R | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LHX3 | c.158G>T p.S53I (on ENST00000371748 / NM_178138.6; = p.S58I on NM_014564.5) | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- LRRTM4 | c.1108A>T p.R370* | Nonsense Mutation (SNP) | VAF 13/261 reads (5%) | called by muse, mutect2
- MCF2 | c.2355A>T p.E785D | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MESD | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2
- MUC4 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- MYCBP2 | c.368G>T p.W123L (on ENST00000357337; = p.W161L on NM_015057.5) | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); called by muse, mutect2
- MYH2 | c.1424G>T p.S475I | Missense Mutation (SNP) | VAF 33/641 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2
- NEUROD1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.082); called by muse, mutect2
- NEXMIF | c.2645C>A p.S882* | Nonsense Mutation (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- NFASC | c.1877-1G>T p.X626_splice (on ENST00000339876 / NM_001378329.1; = p.X622_splice on NM_015090.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- NLRP5 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- NOTCH1 | c.1100-2A>T p.X367_splice | Splice Site (SNP) | VAF 32/663 reads (5%) | called by muse, mutect2
- NRP1 | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2
- OR9Q2 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- PAPOLA | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAX8 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PEX26 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- PKHD1 | c.5132C>A p.A1711D | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- PLEKHA6 | c.1926G>C p.E642D | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- PRADC1 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2
- RNF182 | c.461G>T p.R154M | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2
- RTP3 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SDK1 | c.5378A>T p.Q1793L | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2
- SLC6A3 | c.1641C>A p.H547Q | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2
- SMG6 | c.3662G>T p.R1221L | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- TMEM131 | c.4170G>T p.K1390N | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNRC6B | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.93); called by muse, mutect2
- TOGARAM1 | c.3031T>G p.S1011A | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TPTE2 | c.1105A>C p.T369P (on ENST00000400230 / NM_199254.2; = p.T292P on NM_130785.3) | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- USP6 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 40/683 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- VANGL1 | c.1201A>T p.M401L | Missense Mutation (SNP) | VAF 64/793 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2
- ZAP70 | c.752A>C p.K251T | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.341); called by muse, mutect2
- ZAR1L | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- ZNF808 | c.1334A>T p.H445L | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZSWIM6 | c.3329G>T p.R1110I | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ADGRV1 | c.8640A>T p.A2880= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- ANKRD30B | c.3504A>G p.K1168= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- ASNS | c.810G>C p.L270= | Silent (SNP) | VAF 14/305 reads (5%) | called by muse, mutect2
- CACNA1S | c.5098A>C p.R1700= | Silent (SNP) | VAF 25/774 reads (3%) | called by muse, mutect2
- CCNA2 | c.30G>C p.A10= | Silent (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- DMRTB1 | c.204C>T p.A68= | Silent (SNP) | VAF 18/293 reads (6%) | called by muse, mutect2
- DNAH11 | c.3963A>G p.K1321= | Silent (SNP) | VAF 7/165 reads (4%) | called by muse, mutect2
- DPP10 | c.1515T>C p.S505= | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- EFR3B | c.2352C>A p.P784= | Silent (SNP) | VAF 26/236 reads (11%) | called by mutect2, varscan2
- EIF3K | c.213G>A p.L71= | Silent (SNP) | VAF 20/502 reads (4%) | catalogued as COSV50264276, COSV50264498; called by muse, mutect2
- EYA2 | c.471G>T p.G157= | Silent (SNP) | VAF 24/469 reads (5%) | called by muse, mutect2
- FAM47A | c.771A>G p.R257= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as COSV60499543; called by muse, mutect2, varscan2
- FOXO4 | c.1515C>T p.P505= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- KCNH1 | c.2580G>A p.E860= (on ENST00000271751 / NM_172362.3; = p.E833= on NM_002238.4) | Silent (SNP) | VAF 20/572 reads (3%) | called by muse, mutect2
- KLHL25 | c.1338C>A p.L446= | Silent (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- MYH13 | c.4510C>A p.R1504= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as rs752113103, COSV52846288; called by muse, mutect2
- NDST1 | c.1026G>A p.Q342= | Silent (SNP) | VAF 31/660 reads (5%) | called by muse, mutect2
- NPR1 | c.2808G>T p.R936= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as COSV64117660; called by muse, mutect2
- OR10A3 | c.711C>A p.A237= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as COSV62459893; called by muse, mutect2
- OR2A4 | c.696T>A p.V232= | Silent (SNP) | VAF 26/728 reads (4%) | called by muse, mutect2
- RADX | c.2050C>T p.L684= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- RYR2 | c.12189G>A p.T4063= | Silent (SNP) | VAF 25/403 reads (6%) | catalogued as rs368948386; called by muse, mutect2
- SAMD9 | c.2706G>C p.R902= | Silent (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- SH3RF3 | c.732A>T p.P244= | Silent (SNP) | VAF 37/791 reads (5%) | called by muse, mutect2
- SHANK1 | c.753G>A p.L251= | Silent (SNP) | VAF 19/368 reads (5%) | called by muse, mutect2
- SHOX2 | c.693A>T p.P231= (on ENST00000441443 / NM_006884.3; = p.P255= on NM_003030.4) | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- SLCO5A1 | c.2178C>T p.C726= | Silent (SNP) | VAF 18/400 reads (5%) | catalogued as rs1367361212; called by muse, mutect2
- SRRM4 | c.1185T>C p.Y395= | Silent (SNP) | VAF 30/761 reads (4%) | called by muse, mutect2
- TRIM23 | c.1002G>A p.E334= | Silent (SNP) | VAF 18/291 reads (6%) | called by muse, mutect2
- TTF2 | c.2172A>G p.T724= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ZNF738 | c.30T>G p.P10= | Silent (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- AL121758.1 | c.*480A>G | 3'UTR (SNP) | VAF 13/127 reads (10%) | catalogued as rs1431454185; called by muse, mutect2
- AL353804.4 | chrX:73821516 A>T | 3'Flank (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- CCT5 | c.1179+47T>C | Intron (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- CDH18 | c.1630+16del | Intron (DEL) | VAF 20/152 reads (13%) | catalogued as COSV56899546; called by mutect2, pindel, varscan2
- COLEC11 | c.203-11485C>T | Intron (SNP) | VAF 32/650 reads (5%) | catalogued as COSV52593909, COSV52594800; called by muse, mutect2
- CSHL1 | c.472-111C>T | Intron (SNP) | VAF 26/601 reads (4%) | called by muse, mutect2
- CSNK1G1 | c.182-6568C>T | Intron (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- FBN2 | c.-4G>A | 5'UTR (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- GCK | c.*43G>A | 3'UTR (SNP) | VAF 26/462 reads (6%) | called by muse, mutect2
- KIF17 | c.2020-51G>T | Intron (SNP) | VAF 20/260 reads (8%) | catalogued as COSV99929147; called by muse, mutect2
- LINC01583 | n.252C>A | RNA (SNP) | VAF 28/556 reads (5%) | called by muse, mutect2
- MYO1G | c.1949+94A>G | Intron (SNP) | VAF 32/530 reads (6%) | called by muse, mutect2
- UNKL | c.1585+43C>T | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as rs1235758958; called by muse, mutect2
- ZIC3 | c.-25C>A | 5'UTR (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
